Somatic mutation profile of tumor specimen TCGA-E8-A2EA-01A (aliquot TCGA-E8-A2EA-01A-11D-A17V-08) from TCGA case TCGA-E8-A2EA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 52.5 years (19,159 days).
Specimen TCGA-E8-A2EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5df21201-9db9-49b7-82e9-75556b40225c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A2EA-10A (Blood Derived Normal), aliquot TCGA-E8-A2EA-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a043e88-7ca1-4e2b-892c-676428b06279

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSF2RB | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1389169859, COSV53255555, COSV53259036; called by muse, mutect2, varscan2
- DYRK4 | c.781+1G>A p.X261_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV50541407; called by muse, mutect2, varscan2
- KCNU1 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as rs373537074; called by mutect2, varscan2
- PFKP | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.164); catalogued as rs774474561, COSV66899547; called by mutect2, varscan2
- TBC1D1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV54722576, COSV54725376; called by muse, mutect2, varscan2
- PDS5A | c.1164C>A p.A388= | Silent (SNP) | VAF 100/323 reads (31%) | catalogued as COSV57828062; called by muse, mutect2, varscan2
- STOML3 | c.705C>T p.S235= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV65511242; called by muse, mutect2, varscan2
- ZNF577 | c.759G>T p.R253= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV56816863; called by mutect2, varscan2
- RN7SL484P | chr15:99791928 C>T | 3'Flank (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
